Somatic mutation profile of tumor specimen MP2PRT-PAPBAI-TMP1-A (aliquot MP2PRT-PAPBAI-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPBAI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (960 days).
Specimen MP2PRT-PAPBAI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 979a56c8-98d3-4cd6-aaa6-aed36c6cbd90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBAI-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBAI-NB1-B-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1142b67-7177-42a0-85d1-58d4b9886032

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 133/291 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.1715C>A p.A572E (on ENST00000221891 / NM_001024807.3; = p.A571E on NM_005166.4) | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1473647764; called by muse, mutect2, varscan2
- B3GALT1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 186/401 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59910195; called by muse, mutect2, varscan2
- CACNA1D | c.3134C>T p.T1045M (on ENST00000350061 / NM_001128840.3; = p.T1065M on NM_000720.4) | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773341387; called by muse, mutect2, varscan2
- CACNA1H | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 277/580 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781510850, COSV61999160; called by muse, mutect2, varscan2
- ECE1 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs761609623; called by muse, mutect2
- HMCN2 | c.14510C>T p.P4837L | Missense Mutation (SNP) | VAF 85/458 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs1329518223; called by muse, mutect2, varscan2
- SLC2A14 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs375774869; called by muse, mutect2
- VEGFC | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs554908874, COSV54594769; called by muse, mutect2, varscan2
- ADAMTS13 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 20/522 reads (4%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.499); called by muse, mutect2
- LAMC2 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 134/622 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2
- MAGEC1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 160/534 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- NEURL4 | c.4286G>A p.R1429Q | Missense Mutation (SNP) | VAF 21/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PLOD2 | c.882C>T p.V294= | Splice Region (SNP) | VAF 88/167 reads (53%) | called by muse, mutect2, varscan2
- PPP4R4 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 145/483 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- FAM50B | c.786C>T p.S262= | Silent (SNP) | VAF 213/637 reads (33%) | called by muse, mutect2, varscan2
- MAP3K9 | c.3258G>A p.A1086= (on ENST00000554752 / NM_001284230.1; = p.A1100= on NM_033141.4) | Silent (SNP) | VAF 149/449 reads (33%) | catalogued as rs149882494; called by muse, mutect2, varscan2
- ANO4 | c.-107G>A | 5'UTR (SNP) | VAF 150/334 reads (45%) | catalogued as rs780112580, COSV54620211; called by muse, mutect2, varscan2
